Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A71A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A71A-01A (Primary Tumor).

ICD O-3
Carcinoma, squamous cell NOS
Site Floor of mouth 8070/3
C04.9
7/8/9/13

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Floor of mouth

1 - "Lymph Nodes - Level 2b - Right":

- One lymph node with no evidence of metastatic carcinoma (0/1).

2 - "Supraomohyoid neck dissection specimen - right":

- Three of sixteen lymph nodes at right involved by metastatic carcinoma (3/16), with capsular involvement.
- Salivary submandibular gland with no particularities.

3 - "Left modified radical neck dissection specimen":

- Conglomerate lymph node mass involved by metastatic squamous cell carcinoma measured 5.0 x 3.5 x 3.0 cm.
- Four of twelve lymph nodes involved by metastatic carcinoma (4/12).

4 - "Floor of the mouth lesion":

- Invasive well differentiated squamous cell carcinoma measured 5.0 x 3.5 x 1.5 cm
- Salivary submandibular gland and deep skeletal muscle involved by carcinoma.
- Lymphatic invasion: present.
- Mucosal margin uninvolved by carcinoma.
- Soft tissue deep margin focally involved by carcinoma.

5 - "Floor of the mouth muscle":

- Uninvolved by carcinoma.

* Report synopsis:

Floor of the mouth tumor:

- Squamous cell carcinoma, grade I, with uninvolved margins and presence of lymphatic invasion.

Right neck dissection:

- Three of sixteen lymph nodes involved by metastatic carcinoma (3/16), with capsular involvement.

Left neck dissection:

- Five of thirteen lymph nodes involved by metastatic carcinoma (5/13), with capsular involvement.

Pathological staging: pT4a, pN2c, pMx.

HPV/A Discrepancy		✓

Source: NCI Genomic Data Commons file 2c812428-51a3-4c5b-b3a1-8ac4e7c37594 (TCGA-UF-A71A.1F3355FB-9035-418F-8AD7-B8495FA830D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).